Somatic mutation profile of tumor specimen TCGA-VQ-A8PY-01A (aliquot TCGA-VQ-A8PY-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 47.2 years (17,230 days).
Specimen TCGA-VQ-A8PY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73644364-8b86-4bad-ae92-8ca938fbef1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PY-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PY-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7992807-41bf-486f-b241-a203ab305889

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 18, Nonsense Mutation 5, Frame Shift Del 2, Frame Shift Ins 2, Intron 1, Splice Site 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2158A>C p.I720L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV99288183, COSV99288768; called by muse, mutect2, varscan2
- ABCB1 | c.432A>G p.I144M | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99713300; called by muse, mutect2
- ATG101 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as rs769289413, COSV100401047; called by muse, mutect2, varscan2
- ATXN3L | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV101019429; called by muse, mutect2, varscan2
- CENPK | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99669493; called by muse, mutect2
- CERS3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752230253, COSV52567747; called by muse, mutect2, varscan2
- CFAP43 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99530804; called by muse, mutect2
- CFAP47 | c.4341G>T p.K1447N | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.257); catalogued as COSV100545452; called by muse, mutect2, varscan2
- CORIN | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs143333327, COSV56693523; called by muse, mutect2, varscan2
- CSMD2 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs748711933, COSV53904504, COSV53915786; called by muse, mutect2, varscan2
- CXCR2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs75759064; called by muse, mutect2, varscan2
- CYYR1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100177118; called by muse, mutect2, varscan2
- DDX23 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs760994568, COSV57286621; called by muse, mutect2, varscan2
- DNMT3B | c.2518C>T p.R840* | Nonsense Mutation (SNP) | VAF 67/360 reads (19%) | catalogued as rs1182001726, COSV52416573; called by muse, mutect2, varscan2
- DSEL | c.1508A>G p.K503R | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59489806, COSV59492555; called by muse, mutect2
- ERCC6L2 | c.1407A>C p.K469N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99998704; called by muse, mutect2, varscan2
- ESRRG | c.362A>C p.N121T | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV63150622; called by muse, mutect2, varscan2
- ESX1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV101006474; called by muse, mutect2, varscan2
- EXD1 | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as COSV100153676; called by muse, mutect2
- FLG | c.7390G>A p.G2464R | Missense Mutation (SNP) | VAF 66/736 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as rs1470652785, COSV64244619; called by muse, mutect2
- FMN2 | c.5022C>A p.D1674E | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.417); catalogued as COSV100145618; called by muse, mutect2, varscan2
- FREM2 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs148298275; called by muse, mutect2, varscan2
- HCK | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99394135; called by muse, mutect2, varscan2
- HCN4 | c.2452G>A p.G818S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.477); catalogued as rs1427767002, COSV99983864; called by muse, mutect2, varscan2
- KCNK2 | c.475G>C p.G159R (on ENST00000444842 / NM_001017425.3; = p.G144R on NM_014217.4) | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222205; called by muse, mutect2, varscan2
- KDM3A | c.3647G>A p.R1216Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.112); catalogued as rs144713807; called by muse, mutect2, varscan2
- KY | c.910T>G p.F304V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101415000; called by muse, mutect2
- LDB2 | c.595T>G p.F199V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.403); catalogued as COSV100453946; called by muse, mutect2, varscan2
- LRRTM4 | c.1168T>G p.F390V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV69141343; called by muse, mutect2, varscan2
- MAST3 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761590628, COSV99445555; called by muse, mutect2, varscan2
- METTL21C | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1409843748, COSV57432909; called by muse, mutect2, varscan2
- MGAT2 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100023562, COSV100023660; called by muse, mutect2, varscan2
- MUC6 | c.6553A>C p.T2185P | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.227); catalogued as COSV101424640; called by muse, mutect2, varscan2
- MYO6 | c.179A>G p.E60G | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100889369; called by muse, mutect2
- OR1J2 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV100093284; called by muse, mutect2, varscan2
- OTUD4 | c.2552T>C p.V851A (on ENST00000447906 / NM_001366057.1; = p.V786A on NM_001102653.1) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101486000; called by muse, mutect2, varscan2
- PDE8B | c.2075C>A p.A692D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99366991; called by muse, mutect2, varscan2
- PDZD4 | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 62/195 reads (32%) | catalogued as COSV51250795; called by muse, mutect2, varscan2
- PLSCR2 | c.596A>T p.H199L (on ENST00000497985 / NM_001199978.1; = p.H126L on NM_020359.2) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV100367729; called by muse, mutect2, varscan2
- PPOX | c.988-1G>A p.X330_splice | Splice Site (SNP) | VAF 27/110 reads (25%) | catalogued as CS992477, COSV99237517; called by muse, mutect2, varscan2
- PROK2 | c.373T>G p.C125G (on ENST00000295619 / NM_001126128.2; = p.C104G on NM_021935.4) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99816982; called by muse, mutect2, varscan2
- SCD5 | c.635G>A p.W212* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100124771; called by muse, mutect2, varscan2
- SHANK2 | c.3077C>T p.T1026M | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs377120070; called by muse, mutect2, varscan2
- SIPA1L1 | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100665651; called by muse, mutect2, varscan2
- SLC35B3 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1171854322, COSV100217320; called by muse, mutect2, varscan2
- TACC3 | c.233T>G p.L78R | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100305084; called by muse, mutect2, varscan2
- TMEM117 | c.285G>T p.L95F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV99862874; called by muse, mutect2, varscan2
- UNC13C | c.1637T>C p.L546P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52845905, COSV52871720; called by muse, mutect2, varscan2
- UNC5D | c.1871C>A p.A624E | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766648515, COSV99776086; called by muse, mutect2
- USP44 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 23/144 reads (16%) | catalogued as COSV99311909; called by muse, mutect2, varscan2
- UTP14A | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100928972; called by muse, mutect2, varscan2
- VCAN | c.7762G>T p.E2588* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99426175; called by muse, mutect2
- ZNF567 | c.604A>G p.K202E (on ENST00000536254 / NM_001322913.1; = p.K171E on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100658837; called by muse, mutect2
- CLK4 | c.258_271del p.Y89* | Frame Shift Del (DEL) | VAF 17/149 reads (11%) | called by mutect2, pindel, varscan2
- GSTCD | c.1517T>G p.M506R (on ENST00000360505 / NM_001031720.3; = p.M419R on NM_024751.3) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.058); called by muse, mutect2
- MUC6 | c.4459_4461del p.P1487del | In Frame Del (DEL) | VAF 80/241 reads (33%) | called by pindel, varscan2
- NAA25 | c.2288del p.G763Dfs*12 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- PHLDA1 | c.661_662insGG p.A221Gfs*18 | Frame Shift Ins (INS) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- STARD8 | c.2934_2935dup p.I979Tfs*69 | Frame Shift Ins (INS) | VAF 9/53 reads (17%) | called by mutect2, varscan2
- ATF3 | c.42G>A p.V14= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV100422054; called by muse, mutect2, varscan2
- CACNA1F | c.5769G>A p.Q1923= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100544992; called by muse, mutect2
- DIAPH1 | c.3105C>T p.L1035= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV99526723; called by muse, mutect2
- KRTAP10-11 | c.765C>A p.S255= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100554139; called by muse, mutect2, varscan2
- L1CAM | c.2022T>C p.S674= | Silent (SNP) | VAF 60/489 reads (12%) | catalogued as rs1557091362, COSV100649243; called by muse, mutect2, varscan2
- LANCL1 | c.981G>A p.G327= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99286331; called by muse, mutect2, varscan2
- NAA11 | c.645C>T p.S215= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99727417, COSV99727532; called by muse, mutect2
- OR2L2 | c.753T>C p.Y251= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as COSV100822962, COSV100823860; called by muse, mutect2, varscan2
- OR2M7 | c.21C>T p.T7= | Silent (SNP) | VAF 60/269 reads (22%) | catalogued as COSV100522584; called by muse, mutect2, varscan2
- PER3 | c.858A>G p.E286= | Silent (SNP) | VAF 26/254 reads (10%) | catalogued as COSV100728378; called by muse, mutect2
- PRPH | c.948A>G p.R316= | Silent (SNP) | VAF 15/249 reads (6%) | catalogued as COSV99142003; called by muse, mutect2
- SLC11A2 | c.642C>T p.G214= (on ENST00000394904 / NM_001379455.1; = p.G185= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as COSV50377609; called by muse, mutect2, varscan2
- SNPH | c.843C>T p.F281= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1417204182, COSV100378230; called by muse, mutect2, varscan2
- ST3GAL2 | c.837G>A p.T279= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs749327464, COSV100735628, COSV100735695; called by muse, mutect2
- SYNE1 | c.23664G>A p.Q7888= (on ENST00000367255 / NM_182961.4; = p.Q7817= on NM_033071.3) | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs375008462, COSV99567777; called by muse, mutect2, varscan2
- WBP1L | c.819C>T p.I273= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV64009671; called by muse, mutect2
- WDR17 | c.456C>T p.F152= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as COSV99707777; called by muse, mutect2, varscan2
- ZNF532 | c.1611C>A p.T537= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100266709; called by muse, mutect2
- SNORD116-23 | n.48_53del | RNA (DEL) | VAF 78/463 reads (17%) | called by mutect2, pindel, varscan2
- TAOK2 | chr16:29990904 G>A | 3'Flank (SNP) | VAF 30/105 reads (29%) | catalogued as rs764299214, COSV99662864; called by muse, mutect2, varscan2
- TPM3 | c.244-6872C>T | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99666467; called by muse, mutect2, varscan2
